FM case AD12154 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/cc2f276a-4fa5-44e1-be38-03b81b6ab54b

Male, 55.0 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; metastasis. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
